Somatic mutation profile of tumor specimen 0DUSSV from CCDI case PBCLXN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 23.2 years (8,489 days).
Specimen 0DUSSV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a53eebfb-c17a-49ff-8828-65c4d74c12c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUSSE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a4e89b8-b6d6-4160-8f59-cde7c99da6c2

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Ins 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 56/208 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 88/178 reads (49%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- AC011462.1 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as rs988176395, COSV54199980; called by muse, mutect2
- DUSP26 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99823401; called by muse, mutect2
- MACO1 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1213364187; called by muse, mutect2, varscan2
- SPDYE6 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs1260573221, COSV59504633; called by mutect2, varscan2
- WSB2 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 124/420 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs766702574, COSV57477142; called by muse, mutect2, varscan2
- ZER1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 84/334 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.102); catalogued as rs1445754986, COSV52565666; called by muse, mutect2, varscan2
- ZZEF1 | c.2821G>T p.A941S | Missense Mutation (SNP) | VAF 81/317 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as COSV67556051; called by muse, mutect2, varscan2
- BBS9 | c.409A>T p.N137Y | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DNAH5 | c.12382C>T p.L4128F | Missense Mutation (SNP) | VAF 11/348 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- TBCD | c.1452G>C p.K484N | Missense Mutation (SNP) | VAF 139/383 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TF | c.1843T>G p.C615G | Missense Mutation (SNP) | VAF 18/383 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.251); called by muse, mutect2
- USP34 | c.3946A>T p.R1316W | Missense Mutation (SNP) | VAF 79/274 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BRCA1 | c.4788A>C p.S1596= | Silent (SNP) | VAF 18/415 reads (4%) | called by muse, mutect2
- DPEP3 | c.123C>T p.G41= | Silent (SNP) | VAF 59/247 reads (24%) | called by muse, mutect2, varscan2
- FLNA | c.3708C>T p.G1236= | Silent (SNP) | VAF 71/302 reads (24%) | catalogued as rs200363918; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GLOD5 | c.477C>T p.S159= | Silent (SNP) | VAF 33/510 reads (6%) | called by muse, mutect2
- MLPH | c.978C>T p.S326= | Silent (SNP) | VAF 14/392 reads (4%) | called by muse, mutect2
- CATSPERD | c.-100T>G | 5'UTR (SNP) | VAF 6/33 reads (18%) | catalogued as rs1442996606; called by muse, mutect2, varscan2
- RSPH6A | c.651-57G>T | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
